Gene-level copy-number profile of tumor specimen TCGA-26-5136-01B from TCGA case TCGA-26-5136, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 78.0 years (28,496 days).
Specimen TCGA-26-5136-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.28059e9b-2277-40b5-ba54-5366b7293ced.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-26-5136-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/39a145e0-b429-49b2-b0eb-d3721c22ccf8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 11,339; copy number 2: 44,212; copy number 3: 4,046; copy number 4: 208; copy number 5: 5; copy number 6: 5; copy number 7: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-26-5136-01B-01D-1479-01): tumor purity 0.83, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 14 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:15,246,069–15,522,042, 1 gene, copy number 7 (within-gene range 2–7): JARID2.
- chr6:15,314,920–15,522,300, 3 genes, copy number 7: RNU6-522P, RNU6-645P, 5S_rRNA.
- chr6:20,401,879–20,500,276, 5 genes, copy number 6: E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA.
- chr18:3,571,215–3,656,282, 5 genes, copy number 5: RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2, AP002478.1.

Autosomal genes at a single copy (total copy number 1): 11,339. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
